Somatic mutation profile of tumor specimen TCGA-BS-A0U8-01A (aliquot TCGA-BS-A0U8-01A-11D-A10B-09) from TCGA case TCGA-BS-A0U8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 55.9 years (20,402 days).
Specimen TCGA-BS-A0U8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9293cdd5-6a4d-4f80-bf62-e73d6d1c488d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0U8-10A (Blood Derived Normal), aliquot TCGA-BS-A0U8-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17346058-d27d-4124-b491-e6d65d1f3738

The open-access MAF lists 525 somatic variants for this specimen: 403 protein-altering or splice-affecting, 110 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 110, Frame Shift Del 100, Nonsense Mutation 17, Frame Shift Ins 15, In Frame Del 13, Splice Site 5, RNA 4, Intron 4, Splice Region 3, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.3982C>T p.Q1328* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | hotspot (GDC flag); catalogued as rs398123121, CM930028, COSV57324976; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 53/148 reads (36%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 38/100 reads (38%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 58/124 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.854del p.P285Lfs*21 (on ENST00000642864 / NM_001111125.3; = p.P80Lfs*21 on NM_015075.2) | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs782460038; ClinVar: pathogenic; called by mutect2, pindel
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/194 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 48/123 reads (39%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as rs121909220, CM971274, COSV64290058, COSV64298444, COSV64303803; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.2672del p.N891Tfs*40 | Frame Shift Del (DEL) | VAF 68/198 reads (34%) | catalogued as rs118203724, CD1111250, COSV53764493; ClinVar: not provided / pathogenic; called by pindel, varscan2
- VPS13B | c.5086C>T p.R1696* | Nonsense Mutation (SNP) | VAF 78/199 reads (39%) | catalogued as rs386834093, CM110615, COSV62153546; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547878738, COSV60911544, COSV60913298; called by muse, mutect2, varscan2
- ABHD12 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs746073206, COSV59283683, COSV59288268; called by muse, mutect2, varscan2
- ABHD17B | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61008830; called by muse, mutect2, varscan2
- AC004997.1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); catalogued as rs759489489, COSV53165525; called by muse, mutect2, varscan2
- ACIN1 | c.596G>C p.S199T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); catalogued as rs1186712395, COSV52980619; called by muse, mutect2
- ACLY | c.2956C>T p.R986* | Nonsense Mutation (SNP) | VAF 66/153 reads (43%) | catalogued as rs782631078, COSV59862901; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 47/112 reads (42%) | catalogued as rs746174250; called by mutect2, varscan2
- ADGRG4 | c.8874del p.F2958Lfs*6 | Frame Shift Del (DEL) | VAF 46/262 reads (18%) | catalogued as rs771931957; called by mutect2, pindel, varscan2
- AFP | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV56926639; called by muse, mutect2
- AKAP3 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as rs1220490467, COSV57419479; called by muse, mutect2, varscan2
- ALDH16A1 | c.1430del p.G477Afs*25 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as COSV99512519; called by mutect2, pindel, varscan2
- ALPK2 | c.6381G>A p.M2127I | Missense Mutation (SNP) | VAF 159/336 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV64495947; called by muse, mutect2, varscan2
- ALS2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV51891485; called by muse, mutect2, varscan2
- ANGPTL6 | c.1061del p.G354Afs*115 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs766045464; called by mutect2, pindel, varscan2
- ANKFN1 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs145617071; called by muse, mutect2, varscan2
- AP4M1 | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV57998374; called by muse, mutect2, varscan2
- APBB1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs774997932, COSV54979764; called by muse, mutect2, varscan2
- ARHGAP31 | c.2919C>A p.S973R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV51797572; called by muse, mutect2, varscan2
- ARID1A | c.3916C>T p.Q1306* | Nonsense Mutation (SNP) | VAF 49/110 reads (45%) | catalogued as COSV61385874; called by muse, mutect2, varscan2
- ARID5B | c.1887G>T p.K629N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV54427621; called by muse, mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 114/266 reads (43%) | catalogued as rs772181094; called by mutect2, varscan2
- ASXL3 | c.3134G>A p.G1045D | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV52474343, COSV52476009; called by muse, mutect2
- ATP10D | c.1449A>G p.I483M | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56711838; called by muse, mutect2, varscan2
- ATP13A4 | c.1601A>T p.H534L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55073855; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746368892, COSV59479257; called by muse, mutect2
- ATP6V1B2 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52354861; called by muse, mutect2, varscan2
- AUTS2 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs1277387034, COSV61424313; called by muse, mutect2, varscan2
- AXIN1 | c.2086C>A p.P696T | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51989197, COSV51991828; called by muse, mutect2, varscan2
- AXIN2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61056616, COSV61059970; called by muse, mutect2
- B3GALT1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV59909578; called by muse, mutect2, varscan2
- BAIAP2L1 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.124); catalogued as COSV50059248; called by muse, mutect2, varscan2
- BAZ2B | c.4547C>T p.T1516M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as rs1444509662, COSV58607797; called by muse, mutect2, varscan2
- BCKDHB | c.612del p.F204Lfs*26 | Frame Shift Del (DEL) | VAF 117/317 reads (37%) | catalogued as rs1210649507; called by mutect2, varscan2
- BCL6 | c.1418del p.P473Rfs*117 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as COSV51655892; called by mutect2, pindel, varscan2
- BCL9L | c.1478del p.P493Rfs*9 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as COSV52683193; called by mutect2, pindel, varscan2
- BCOR | c.2941A>G p.T981A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60715378; called by muse, mutect2, varscan2
- BRCA2 | c.8663G>A p.R2888H | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs80359124, COSV66448556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRICD5 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as rs374169284; called by muse, mutect2, varscan2
- BRSK1 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58669137; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- C1QB | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs770317321, COSV59245894; called by muse, mutect2, varscan2
- C5 | c.4196A>G p.Y1399C | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.319); catalogued as COSV56331210; called by muse, mutect2, varscan2
- C9orf50 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs199839916, COSV65252846; called by muse, mutect2, varscan2
- CAAP1 | c.571del p.I191Ffs*2 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as rs754356646, COSV61700397; called by mutect2, varscan2
- CACHD1 | c.1950A>G p.L650= | Splice Region (SNP) | VAF 27/67 reads (40%) | catalogued as COSV51558670; called by muse, mutect2, varscan2
- CACNB1 | c.1613G>A p.G538D | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV59999930; called by muse, mutect2, varscan2
- CALCOCO1 | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as COSV50420567; called by muse, mutect2, varscan2
- CAMTA1 | c.510G>T p.Q170H | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV57921118; called by muse, mutect2, varscan2
- CARD11 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs868687398, COSV67800951, COSV67803823; called by muse, mutect2, varscan2
- CATSPER3 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775375224, COSV50948923; called by muse, mutect2, varscan2
- CC2D2A | c.1948C>G p.L650V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1382964089, COSV67505280; called by muse, mutect2, varscan2
- CCDC103 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.704); catalogued as rs756958260, COSV53652941; called by muse, mutect2, varscan2
- CCDC39 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs772023939, COSV56491317; called by muse, mutect2, varscan2
- CCNYL1 | c.853A>G p.N285D (on ENST00000295414 / NM_001330218.2; = p.N215D on NM_152523.2) | Missense Mutation (SNP) | VAF 9/288 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54941555; called by muse, mutect2
- CDH1 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450920019, COSV55738895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1283+2T>C p.X428_splice | Splice Site (SNP) | VAF 19/100 reads (19%) | catalogued as COSV58115882; called by muse, mutect2, varscan2
- CDK6 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 83/188 reads (44%) | catalogued as COSV56011936; called by muse, mutect2, varscan2
- CEACAM21 | c.799G>A p.A267T (on ENST00000401445 / NM_001098506.4; = p.A266T on NM_033543.6) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1555794996, COSV51815961; called by muse, mutect2, varscan2
- CEP104 | c.2704A>G p.K902E | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV65519124; called by muse, mutect2, varscan2
- CEP290 | c.7341dup p.L2448Tfs*8 | Frame Shift Ins (INS) | VAF 36/96 reads (38%) | catalogued as rs281865189; ClinVar: not provided; called by mutect2, varscan2
- CERS1 | c.425T>C p.M142T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); catalogued as COSV55930508; called by muse, mutect2, varscan2
- CHPF2 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV50397958; called by muse, mutect2, varscan2
- CHRNA10 | c.986T>C p.V329A | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51706477; called by muse, mutect2
- CIRBP | c.511_513del p.N171del | In Frame Del (DEL) | VAF 76/208 reads (37%) | catalogued as rs1224938314; called by mutect2, pindel, varscan2
- CLCN6 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV56742498; called by muse, mutect2, varscan2
- CNNM4 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs775648616, COSV65660535; called by muse, mutect2, varscan2
- COBL | c.3226G>T p.D1076Y | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV54355319; called by muse, mutect2, varscan2
- COBL | c.2836G>A p.V946M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV54355336; called by muse, mutect2
- COL21A1 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55175780; called by muse, mutect2, varscan2
- COL4A4 | c.3350C>A p.P1117H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV61635488; called by muse, mutect2
- COL6A1 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62611569; called by muse, mutect2, varscan2
- CPXM1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as rs770503107, COSV66046471; called by muse, mutect2, varscan2
- CRACR2A | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52917192; called by muse, mutect2, varscan2
- CRB1 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV66329814; called by muse, mutect2, varscan2
- CSPG4 | c.4879del p.Q1627Sfs*2 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs1332907606; called by mutect2, varscan2
- CTLA4 | c.529del p.Y177Ifs*10 | Frame Shift Del (DEL) | VAF 154/340 reads (45%) | catalogued as COSV55593336; called by mutect2, varscan2
- CUL7 | c.2585A>T p.K862M | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54818871, COSV54820806; called by muse, mutect2, varscan2
- CYP2S1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs767569140, COSV59507061; called by muse, mutect2, varscan2
- CYP4F12 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs369172315; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 25/48 reads (52%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DBF4B | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs756027049, COSV59260645; called by muse, mutect2, varscan2
- DCST2 | c.1213dup p.Y405Lfs*30 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as rs774746029; called by mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX39A | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54393047; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 58/190 reads (31%) | catalogued as rs773554787; called by mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs771360300; called by mutect2, varscan2
- DLAT | c.342del p.E115Rfs*10 | Frame Shift Del (DEL) | VAF 59/146 reads (40%) | catalogued as rs782180715; called by mutect2, varscan2
- DNAH7 | c.3221dup p.L1074Ffs*4 | Frame Shift Ins (INS) | VAF 42/111 reads (38%) | catalogued as rs763352877; called by mutect2, varscan2
- DOCK2 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV56980880; called by muse, mutect2, varscan2
- DOK5 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV52815994, COSV52824312; called by muse, mutect2, varscan2
- DOLPP1 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs745414713, COSV59910869; called by muse, mutect2, varscan2
- DOP1A | c.6173A>G p.K2058R | Missense Mutation (SNP) | VAF 187/437 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52715903; called by muse, mutect2, varscan2
- DPYSL2 | c.830A>G p.E277G | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV60784836; called by muse, mutect2, varscan2
- DYRK1A | c.516+2T>C p.X172_splice | Splice Site (SNP) | VAF 52/121 reads (43%) | catalogued as CS160126, COSV58296464; called by muse, mutect2, varscan2
- EBF2 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV68776622; called by muse, mutect2, varscan2
- EGLN3 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51656013; called by muse, mutect2, varscan2
- EIF2S3 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1246329689, COSV53407790; called by muse, mutect2, varscan2
- ELL | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs964006105, COSV53215198; called by muse, mutect2, varscan2
- EPG5 | c.6950C>T p.A2317V | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56354653; called by muse, mutect2, varscan2
- EPRS1 | c.2087del p.P696Rfs*4 | Frame Shift Del (DEL) | VAF 45/388 reads (12%) | catalogued as COSV65098937; called by mutect2, pindel, varscan2
- EPS8L1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1436085091, COSV52385248; called by muse, mutect2, varscan2
- ERCC1 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV50005123; called by muse, mutect2, varscan2
- ESRRA | c.47A>C p.E16A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as COSV50007829; called by muse, mutect2, varscan2
- EXOC2 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100034040, COSV57870445; called by muse, mutect2, varscan2
- EZHIP | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.133); catalogued as rs1557318576, COSV57955028, COSV57957317; called by muse, mutect2, varscan2
- FAM110B | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64067370; called by muse, mutect2, varscan2
- FAM166C | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1273582715, COSV61593904; called by muse, mutect2
- FAM24B | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.55); catalogued as rs770495348, COSV59027530; called by muse, mutect2, varscan2
- FAM76A | c.359A>T p.D120V | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50549711; called by muse, mutect2, varscan2
- FAT1 | c.10268C>T p.T3423M | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs1282821100, COSV71674099; called by muse, mutect2, varscan2
- FCRL2 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63832854; called by muse, mutect2, varscan2
- FGA | c.1198T>G p.S400A | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.133); catalogued as rs761337850, COSV57399603; called by muse, mutect2, varscan2
- FLNC | c.6190G>A p.V2064M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756710545, COSV57962444; called by muse, mutect2, varscan2
- FMR1NB | c.630G>A p.R210= | Splice Region (SNP) | VAF 155/382 reads (41%) | catalogued as COSV63272959; called by muse, mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FOSL1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57029036; called by muse, mutect2, varscan2
- FREM2 | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54848382; called by muse, mutect2, varscan2
- FURIN | c.1849G>T p.G617W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51578893; called by muse, mutect2, varscan2
- FYCO1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 46/122 reads (38%) | catalogued as COSV56118724; called by muse, mutect2, varscan2
- GANAB | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755868952, COSV60467846; called by muse, mutect2, varscan2
- GFRA3 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.108); catalogued as COSV51230717; called by muse, mutect2, varscan2
- GLE1 | c.1349G>A p.S450N | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59409872; called by muse, mutect2, varscan2
- GLYCTK | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as rs1336899870, COSV59794538; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 18/42 reads (43%) | catalogued as rs749150409; called by mutect2, varscan2
- GNA11 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383785285, COSV50019400; called by muse, mutect2, varscan2
- GNA14 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1197170791, COSV59027967; called by muse, mutect2, varscan2
- GPR146 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.761); catalogued as rs772239205, COSV52466964; called by muse, mutect2, varscan2
- GRIK3 | c.2383A>G p.M795V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs989970604, COSV66137296; called by muse, mutect2, varscan2
- GRIN2B | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV74207301; called by muse, mutect2, varscan2
- GRIP1 | c.3118G>T p.G1040* (on ENST00000359742 / NM_001379345.1; = p.G988* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | catalogued as COSV54037636; called by muse, mutect2
- GZMB | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1025233053, COSV53543019; called by muse, mutect2
- HDAC1 | c.1402_1404del p.E468del | In Frame Del (DEL) | VAF 39/92 reads (42%) | catalogued as rs771427696; called by pindel, varscan2
- HDGFL2 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56684561; called by muse, mutect2, varscan2
- HESX1 | c.533del p.N178Ifs*10 | Frame Shift Del (DEL) | VAF 104/249 reads (42%) | catalogued as rs759180706; called by mutect2, varscan2
- HLA-B | c.721T>C p.W241R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1322740343, COSV101318178, COSV69521251; called by muse, mutect2
- HPSE | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs368010347; called by muse, mutect2
- HS6ST2 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63717056; called by muse, mutect2, varscan2
- HSPH1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748889774, COSV60712426; called by muse, varscan2
- HTR2A | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780635453, CM157842, COSV66327517; called by muse, mutect2, varscan2
- HTR2C | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.442); catalogued as COSV52221466; called by muse, mutect2, varscan2
- HTT | c.8870G>A p.R2957Q | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779386355, COSV61867520; called by muse, mutect2, varscan2
- IGF2R | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1326531060, COSV63631927; called by muse, mutect2, varscan2
- IGLV2-11 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as rs751199675; called by muse, mutect2
- IGSF10 | c.6335C>T p.A2112V | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs377142937, COSV56388172; called by muse, mutect2, varscan2
- IGSF6 | c.680_682del p.N227del | In Frame Del (DEL) | VAF 94/254 reads (37%) | catalogued as rs562061536; called by pindel, varscan2
- IGSF8 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as rs368150183, COSV58758961; called by muse, mutect2, varscan2
- IGSF9 | c.154dup p.L52Pfs*27 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | catalogued as rs753928344; called by mutect2, varscan2
- INPP4A | c.2090T>C p.L697P (on ENST00000074304 / NM_001134224.1; = p.L658P on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50816896; called by muse, mutect2, varscan2
- INSR | c.3809G>A p.R1270H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746000108, COSV57158214; called by muse, mutect2, varscan2
- INTS1 | c.2300T>C p.M767T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs376514865; called by muse, mutect2, varscan2
- IPO9 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV64235333; called by muse, mutect2, varscan2
- JPH3 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs755158194, COSV52472663; called by mutect2, varscan2
- KCNH7 | c.2245del p.A749Qfs*11 | Frame Shift Del (DEL) | VAF 60/180 reads (33%) | catalogued as rs757276514; called by mutect2, pindel, varscan2
- KDM5A | c.3041G>A p.G1014D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV66995496; called by muse, mutect2
- KHDRBS3 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV63422973; called by muse, mutect2, varscan2
- KIR3DL2 | c.637del p.L213Wfs*4 | Frame Shift Del (DEL) | VAF 88/276 reads (32%) | catalogued as rs1313940189; called by pindel, varscan2
- KLHL4 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV64146642; called by muse, mutect2, varscan2
- KMT2B | c.3602del p.P1201Rfs*154 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as COSV55870773; called by mutect2, pindel, varscan2
- KRTAP4-3 | c.277A>G p.S93G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66940993; called by muse, varscan2
- LARGE2 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs758493715, COSV57656118; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LAYN | c.331C>T p.R111C (on ENST00000375615 / NM_001258390.1; = p.R103C on NM_178834.5) | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as rs146459063; called by muse, mutect2, varscan2
- LIG1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54395071; called by muse, mutect2, varscan2
- LRP4 | c.5335G>A p.E1779K | Missense Mutation (SNP) | VAF 120/533 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV66138005; called by muse, mutect2, varscan2
- LTF | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as COSV51611120; called by muse, mutect2, varscan2
- MAK | c.503del p.P168Lfs*5 | Frame Shift Del (DEL) | VAF 39/108 reads (36%) | catalogued as COSV57565734; called by mutect2, pindel, varscan2
- MAML2 | c.3220A>G p.T1074A | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV73264483; called by muse, mutect2, varscan2
- MAST3 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs199503705, COSV53225421; called by muse, mutect2, varscan2
- MAST3 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV53225432; called by muse, mutect2, varscan2
- MCF2L | c.493G>A p.V165M (on ENST00000375608; = p.V133M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375295899; called by muse, mutect2, varscan2
- MCM2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as rs190889381, COSV54035084; called by muse, mutect2, varscan2
- MCTP1 | c.2719_2720+1del p.X907_splice | Splice Site (DEL) | VAF 60/152 reads (39%) | catalogued as rs764457576; called by pindel, varscan2
- MDH1B | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs369119966; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MED12 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61352085; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 78/192 reads (41%) | catalogued as rs780635289; called by mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 155/474 reads (33%) | catalogued as rs866533107; called by mutect2, pindel, varscan2
- MKRN3 | c.890T>C p.M297T | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs147605349; called by muse, mutect2, varscan2
- MORC1 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.35); catalogued as rs754083133, COSV51714624, COSV51728285; called by muse, mutect2, varscan2
- MSC | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57697357; called by muse, mutect2, varscan2
- MTMR12 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV53787096; called by muse, mutect2, varscan2
- MYO1H | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368271068; called by muse, mutect2, varscan2
- MYO7B | c.2323C>T p.R775W | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1019917444, COSV67350749; called by muse, mutect2, varscan2
- NCAM1 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as COSV57522655; called by muse, mutect2, varscan2
- NCBP3 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs763908946, COSV50106185; called by muse, mutect2, varscan2
- NCOA7 | c.1648A>G p.S550G | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV57658750; called by muse, mutect2
- NCOR1 | c.4444C>T p.R1482W | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1000518180, COSV51963569; called by muse, mutect2
- NDUFB7 | c.248A>C p.E83A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV53108918; called by muse, mutect2, varscan2
- NEFL | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1353746166, COSV55338152; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 52/60 reads (87%) | catalogued as rs759081520; called by mutect2, varscan2
- NFX1 | c.2464T>C p.C822R | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59312570; called by muse, mutect2, varscan2
- NIBAN1 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 21/191 reads (11%) | catalogued as COSV62287131; called by muse, mutect2, varscan2
- NINL | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1347083490, COSV54007396; called by muse, mutect2, varscan2
- NKAIN1 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs760331473, COSV55273787; called by muse, mutect2, varscan2
- NOBOX | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748472205, COSV56193950, COSV56194458; called by muse, mutect2
- NOL6 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53044974; called by muse, mutect2, varscan2
- NOTCH1 | c.5752G>A p.A1918T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53034274; called by muse, mutect2, varscan2
- NOTUM | c.1241G>T p.W414L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68826561; called by mutect2, varscan2
- NPIPB15 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.305); catalogued as rs564252734, COSV70437801; called by muse, mutect2
- NPR3 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54092051; called by muse, mutect2, varscan2
- NPTN | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.298); catalogued as rs757426460, COSV54739272; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 55/119 reads (46%) | catalogued as rs774343392; called by mutect2, varscan2
- NSUN2 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.044); catalogued as rs762223733, COSV52956553; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 71/176 reads (40%) | catalogued as rs760869296; called by mutect2, varscan2
- NYNRIN | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66844387, COSV66845180; called by muse, mutect2, varscan2
- OCA2 | c.2264T>G p.L755R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62355161; called by muse, mutect2
- OLFML2B | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as rs747630822, COSV54199458; called by muse, mutect2, varscan2
- OR10P1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs140326016; called by muse, mutect2, varscan2
- OR10Q1 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs751729524, COSV57470591, COSV57471186, COSV99079566; called by muse, mutect2, varscan2
- OR11L1 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV63315425; called by muse, mutect2, varscan2
- OR4C15 | c.818T>C p.V273A (on ENST00000314644; = p.V219A on NM_001001920.2) | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as rs1295443957, COSV58954934; called by muse, mutect2, varscan2
- OR8G2P | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs369748247; called by muse, mutect2, varscan2
- OR8I2 | c.532del p.C178Vfs*7 | Frame Shift Del (DEL) | VAF 65/143 reads (45%) | catalogued as rs112181516, COSV56167552; called by mutect2, varscan2
- PADI6 | c.1425G>A p.W475* | Nonsense Mutation (SNP) | VAF 43/86 reads (50%) | catalogued as COSV61885547; called by muse, mutect2, varscan2
- PCDH15 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs755925634, COSV57316111, COSV57374274; called by muse, mutect2, varscan2
- PCDH19 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV55260231; called by muse, mutect2, varscan2
- PCDHA9 | c.2126G>A p.S709N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV65330571, COSV65331419; called by muse, mutect2, varscan2
- PCDHB4 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as rs781908551, COSV52024533; called by muse, mutect2, varscan2
- PCDHGB1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as rs1440968204, COSV54010164; called by muse, mutect2, varscan2
- PCNX3 | c.5562del p.V1855Wfs*29 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs763360634; called by mutect2, pindel, varscan2
- PDE10A | c.1507T>C p.F503L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV63090707, COSV63103684; called by muse, mutect2, varscan2
- PGBD2 | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61400227; called by muse, mutect2, varscan2
- PGM2L1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV53348903; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs769717544; called by mutect2, varscan2
- PHLDB1 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs782500122, COSV61881276; called by muse, mutect2, varscan2
- PIWIL3 | c.1928C>G p.T643R | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV59997523; called by muse, mutect2
- PLA2G4A | c.1119dup p.M374Yfs*6 | Frame Shift Ins (INS) | VAF 123/319 reads (39%) | catalogued as rs750546323; called by mutect2, pindel, varscan2
- PLCH1 | c.2407G>A p.E803K (on ENST00000340059 / NM_001130960.2; = p.E815K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV58202770, COSV58207751; called by muse, mutect2, varscan2
- PLEC | c.7931G>A p.R2644H (on ENST00000322810 / NM_201380.4; = p.R2534H on NM_000445.5) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs782232833, COSV59680611; called by muse, mutect2, varscan2
- PLXNB3 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs539782168, COSV62795819, COSV62798332; called by muse, varscan2
- PLXNC1 | c.4246C>T p.L1416F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51581506; called by muse, mutect2, varscan2
- PM20D2 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs758498787, COSV51530723; called by muse, mutect2, varscan2
- POM121 | c.1023-2A>G p.X341_splice (on ENST00000434423; = p.X76_splice on NM_172020.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 86/222 reads (39%) | catalogued as COSV57522473; called by muse, mutect2, varscan2
- POTEH | c.281T>A p.L94H | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as COSV58885918; called by muse, mutect2, varscan2
- PPP1R16B | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV55382588; called by muse, mutect2
- PRDM5 | c.1356G>T p.Q452H | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53365619; called by muse, mutect2, varscan2
- PRKD2 | c.720_722del p.S242del | In Frame Del (DEL) | VAF 86/198 reads (43%) | catalogued as rs1045798607; called by pindel, varscan2
- PRR30 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs768172063, COSV53205301; called by muse, mutect2
- QPCTL | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs373561307, COSV50004577; called by muse, mutect2, varscan2
- RANBP6 | c.2918del p.N973Mfs*12 | Frame Shift Del (DEL) | VAF 108/250 reads (43%) | catalogued as rs746880803; called by mutect2, varscan2
- RAPH1 | c.769A>G p.R257G (on ENST00000319170 / NM_213589.3; = p.R309G on NM_203365.4) | Missense Mutation (SNP) | VAF 148/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57356408; called by muse, mutect2, varscan2
- RBM27 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 52/109 reads (48%) | catalogued as COSV54589288; called by muse, mutect2, varscan2
- RBPJ | c.252del p.E85Nfs*21 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | catalogued as rs761285857; called by mutect2, varscan2
- RHOBTB1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772813661, COSV61959511; called by muse, mutect2, varscan2
- RIMS4 | c.728A>G p.D243G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.404); catalogued as COSV65720539; called by muse, mutect2, varscan2
- RLF | c.3894T>A p.N1298K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV65652853; called by muse, mutect2, varscan2
- RNF213 | c.13295C>T p.A4432V | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768697961, COSV60400262; called by muse, mutect2, varscan2
- RNF43 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs200066146, COSV68456876; called by muse, mutect2, varscan2
- ROCK2 | c.412del p.W138Gfs*31 | Frame Shift Del (DEL) | VAF 65/164 reads (40%) | catalogued as rs755738345; called by mutect2, pindel, varscan2
- RPL26L1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as rs991936308, COSV54200205; called by muse, mutect2, varscan2
- RUSC2 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63429927; called by muse, mutect2, varscan2
- S1PR2 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as rs377336539; called by muse, mutect2, varscan2
- SCIN | c.1761G>T p.E587D (on ENST00000297029 / NM_001112706.3; = p.E340D on NM_033128.3) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51697486, COSV51698475; called by muse, mutect2, varscan2
- SCN11A | c.712+1G>A p.X238_splice | Splice Site (SNP) | VAF 35/98 reads (36%) | catalogued as rs768647693, COSV56566760; called by muse, mutect2, varscan2
- SDC4 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs1219022595, COSV65595765, COSV65595933; called by muse, mutect2, varscan2
- SDK1 | c.5237G>A p.S1746N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs760558273, COSV67384329; called by muse, mutect2, varscan2
- SEMA5A | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV66802916; called by muse, mutect2
- SESTD1 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as rs745954497, COSV58932492; called by muse, mutect2, varscan2
- SH2D4B | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs753656530, COSV57900187; called by muse, mutect2, varscan2
- SHC3 | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV65440228; called by muse, mutect2
- SHROOM2 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV66609791; called by muse, mutect2, varscan2
- SHROOM2 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV66609801; called by muse, mutect2, varscan2
- SLC32A1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.349); catalogued as COSV54148043, COSV54148124; called by muse, mutect2, varscan2
- SLC35A2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); catalogued as rs782485193, COSV54431520, COSV99504041; called by muse, mutect2, varscan2
- SLC5A2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs750695233, COSV57893829; called by muse, mutect2, varscan2
- SLC6A19 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201070872; called by muse, mutect2, varscan2
- SLC9A3 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53804488; called by muse, mutect2
- SLC9A9 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57241182; called by muse, mutect2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 64/130 reads (49%) | catalogued as rs747319777; called by mutect2, varscan2
- SMAD7 | c.626dup p.P210Sfs*25 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs747624971; called by mutect2, varscan2
- SPHK1 | c.83G>A p.G28D (on ENST00000392496 / NM_001355139.2; = p.G42D on NM_021972.4) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60066740; called by muse, mutect2, varscan2
- SPRY2 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV65701701; called by muse, mutect2, varscan2
- SSBP4 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs768063787, COSV54211991; called by muse, mutect2, varscan2
- SSH1 | c.2288A>G p.D763G | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.388); catalogued as COSV58459150; called by muse, mutect2, varscan2
- STAB2 | c.3506C>T p.A1169V | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66344930; called by muse, mutect2, varscan2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs1553764068; called by mutect2, pindel, varscan2
- SYNJ1 | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.087); catalogued as rs778501870, COSV59154688; called by muse, mutect2, varscan2
- TAF1 | c.1034G>A p.G345D (on ENST00000373790 / NM_138923.4; = p.G366D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52122295; called by muse, mutect2
- TAF15 | c.1589dup p.Y531Lfs*56 (on ENST00000605844 / NM_139215.3; = p.Y528Lfs*56 on NM_003487.4) | Frame Shift Ins (INS) | VAF 111/308 reads (36%) | catalogued as rs770087298; called by mutect2, varscan2
- TBL1X | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV54286640; called by muse, mutect2, varscan2
- TCF7L2 | c.85_87del p.E29del | In Frame Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs754968616; called by pindel, varscan2
- TDRD5 | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 89/181 reads (49%) | catalogued as COSV54248620; called by muse, mutect2, varscan2
- TECPR1 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs1396899737, COSV65783443, COSV65784777; called by muse, mutect2, varscan2
- TECTA | c.4675C>T p.R1559W | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1490748218, COSV50688969; called by muse, mutect2, varscan2
- THSD4 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769871112, COSV55963686, COSV55980879; called by muse, mutect2, varscan2
- TMEM120A | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58694957; called by muse, mutect2, varscan2
- TMEM132B | c.2738T>C p.L913P | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54765688; called by mutect2, varscan2
- TMEM8B | c.819+6C>T | Splice Region (SNP) | VAF 58/108 reads (54%) | catalogued as rs755434871, COSV65077644; called by muse, mutect2, varscan2
- TNIK | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs373386336, COSV52692394; called by muse, mutect2, varscan2
- TNRC18 | c.5422G>T p.E1808* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV68169291; called by muse, mutect2
- TRGV3 | c.5G>T p.R2L | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs371353613; called by muse, mutect2
- TRIM67 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.105); catalogued as rs185070039; called by muse, mutect2, varscan2
- TRPV6 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1191758873, COSV63891960; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTN | c.57233A>G p.H19078R (on ENST00000591111; = p.H11654R on NM_003319.4) | Missense Mutation (SNP) | VAF 13/176 reads (7%) | PolyPhen possibly damaging (0.738); catalogued as COSV60272796; called by muse, mutect2
- TTN | c.19313T>C p.V6438A (on ENST00000591111; = p.V5511A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | PolyPhen benign (0.107); catalogued as COSV60272826; called by muse, mutect2, varscan2
- TULP4 | c.3328C>T p.P1110S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV65579600; called by muse, mutect2, varscan2
- TUSC3 | c.401A>T p.D134V | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65885890; called by muse, mutect2
- U2SURP | c.1648A>T p.T550S | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.353); catalogued as COSV67532744; called by muse, mutect2, varscan2
- UBQLN3 | c.389del p.P130Lfs*5 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | catalogued as COSV61163552; called by mutect2, pindel, varscan2
- UBTF | c.2099G>T p.G700V | Missense Mutation (SNP) | VAF 115/277 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.348); catalogued as COSV57187950; called by muse, mutect2, varscan2
- UBXN11 | c.1206G>T p.K402N (on ENST00000374221 / NM_183008.2; = p.K369N on NM_145345.2) | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV53331928; called by muse, mutect2, varscan2
- UNC79 | c.7844A>G p.Q2615R (on ENST00000393151 / NM_001346218.2; = p.Q2438R on NM_020818.5) | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV56405135; called by muse, mutect2, varscan2
- URB2 | c.3155G>A p.G1052D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV50987439; called by muse, mutect2, varscan2
- USP26 | c.1461del p.F487Lfs*40 | Frame Shift Del (DEL) | VAF 31/67 reads (46%) | catalogued as rs761320003; called by mutect2, varscan2
- USP9X | c.7442C>T p.A2481V | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as COSV61073916; called by muse, mutect2, varscan2
- USPL1 | c.1985A>G p.N662S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs375316377, COSV55001783; called by muse, mutect2, varscan2
- VTA1 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1316760779, COSV62660085; called by muse, mutect2
- WARS1 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs199806688, COSV59927094; called by muse, mutect2, varscan2
- WDFY3 | c.6577C>T p.R2193C | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1481597056, COSV55711247; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- XPO6 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.944); catalogued as COSV58970116; called by muse, mutect2, varscan2
- XYLB | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV52915275; called by muse, mutect2, varscan2
- ZBED1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as rs1422540072, COSV58137887; called by muse, mutect2, varscan2
- ZBED4 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs868834816, COSV53467685; called by muse, mutect2, varscan2
- ZBTB4 | c.2689G>T p.G897W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60141879; called by muse, mutect2, varscan2
- ZC3H13 | c.3904C>T p.R1302* | Nonsense Mutation (SNP) | VAF 113/274 reads (41%) | catalogued as rs1228647757, COSV54461155; called by muse, mutect2, varscan2
- ZCCHC7 | c.1625del p.K542Sfs*9 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs760783608; called by mutect2, varscan2
- ZHX1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV52877496; called by muse, mutect2
- ZNF280A | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs780225696, COSV57480372; called by muse, mutect2
- ZNF317 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.981); catalogued as rs752385341, COSV56111181; called by muse, mutect2, varscan2
- ZNF346 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV56156830, COSV56157858; called by muse, mutect2, varscan2
- ZNF385D | c.778A>T p.T260S | Missense Mutation (SNP) | VAF 120/273 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.031); catalogued as COSV55770232; called by muse, mutect2, varscan2
- ZNF638 | c.3428A>G p.Q1143R | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV52494379; called by muse, mutect2, varscan2
- ZNF648 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1442861431, COSV60572388; called by muse, mutect2, varscan2
- ZSCAN18 | c.1418dup p.A474Rfs*16 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | catalogued as rs1248773350; called by mutect2, pindel, varscan2
- ACAT2 | c.617del p.L206Wfs*23 | Frame Shift Del (DEL) | VAF 43/114 reads (38%) | called by mutect2, pindel, varscan2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 57/115 reads (50%) | called by mutect2, varscan2
- ADAM23 | c.1955_1958del p.K652Mfs*37 | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | called by mutect2, pindel, varscan2
- AFF2 | c.2933del p.K978Rfs*65 | Frame Shift Del (DEL) | VAF 81/186 reads (44%) | called by mutect2, pindel, varscan2
- ARFGAP3 | c.741dup p.Q248Tfs*7 | Frame Shift Ins (INS) | VAF 29/318 reads (9%) | called by mutect2, pindel
- ARID1A | c.3281del p.K1094Sfs*67 | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | called by mutect2, pindel, varscan2
- ATM | c.4741del p.I1581Sfs*20 | Frame Shift Del (DEL) | VAF 56/170 reads (33%) | called by mutect2, pindel, varscan2
- AUH | c.926_928del p.E309del | In Frame Del (DEL) | VAF 75/187 reads (40%) | called by pindel, varscan2
- BRCA2 | c.10248del p.K3416Nfs*11 | Frame Shift Del (DEL) | VAF 16/31 reads (52%) | called by mutect2, pindel, varscan2
- BRWD1 | c.2326_2329del p.K776Lfs*49 | Frame Shift Del (DEL) | VAF 54/140 reads (39%) | called by pindel, varscan2
- CDH23 | c.2719del p.V907Sfs*15 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- CDH7 | c.1124del p.P375Lfs*25 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | called by mutect2, pindel, varscan2
- CFAP44 | c.2665del p.S889Lfs*5 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 36/99 reads (36%) | called by mutect2, pindel, varscan2
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 71/189 reads (38%) | called by mutect2, pindel, varscan2
- COL8A1 | c.2015dup p.N673Qfs*91 | Frame Shift Ins (INS) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- COMMD9 | c.278del p.N93Tfs*6 | Frame Shift Del (DEL) | VAF 58/173 reads (34%) | called by mutect2, pindel, varscan2
- COPS4 | c.929_931del p.L310del | In Frame Del (DEL) | VAF 40/114 reads (35%) | called by pindel, varscan2
- CTNNA3 | c.1889del p.P630Qfs*33 | Frame Shift Del (DEL) | VAF 43/104 reads (41%) | called by mutect2, pindel, varscan2
- CUL5 | c.1694del p.N565Ifs*18 | Frame Shift Del (DEL) | VAF 40/107 reads (37%) | called by mutect2, varscan2
- DOCK1 | c.1368_1370del p.D456del | In Frame Del (DEL) | VAF 80/261 reads (31%) | called by mutect2, pindel, varscan2
- DOCK11 | c.848del p.K283Rfs*4 | Frame Shift Del (DEL) | VAF 45/116 reads (39%) | called by mutect2, pindel, varscan2
- EHF | c.759_761del p.K253del | In Frame Del (DEL) | VAF 48/109 reads (44%) | called by pindel, varscan2
- EIF3G | c.339del p.G114Dfs*15 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- EQTN | c.758del p.L253Wfs*8 | Frame Shift Del (DEL) | VAF 81/203 reads (40%) | called by mutect2, pindel, varscan2
- FBLN5 | c.887del p.N296Tfs*30 | Frame Shift Del (DEL) | VAF 47/128 reads (37%) | called by mutect2, pindel, varscan2
- FMOD | c.799del p.A267Rfs*14 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | called by mutect2, pindel, varscan2
- GNPNAT1 | c.162del p.F54Lfs*7 | Frame Shift Del (DEL) | VAF 32/107 reads (30%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- HNRNPUL1 | c.2171del p.P724Qfs*191 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | called by mutect2, pindel, varscan2
- IGLV2-18 | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF12 | c.1408_1410del p.L470del (on ENST00000640217; = p.L332del on NM_138424.1) | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by pindel, varscan2
- KLB | c.2605del p.V869Cfs*39 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- KMT2E | c.138_139del p.T47Qfs*18 | Frame Shift Del (DEL) | VAF 50/212 reads (24%) | called by pindel, varscan2
- LDHAL6A | c.354_358del p.K118Nfs*19 | Frame Shift Del (DEL) | VAF 73/176 reads (41%) | called by mutect2, pindel, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, varscan2
- MSLN | c.1531del p.A511Pfs*6 (on ENST00000382862 / NM_013404.4; = p.A503Pfs*6 on NM_005823.6) | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- MST1 | c.920del p.G307Afs*219 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | called by mutect2, pindel, varscan2
- NEB | c.5375del p.K1792Rfs*7 | Frame Shift Del (DEL) | VAF 105/305 reads (34%) | called by mutect2, pindel, varscan2
- NRIP1 | c.1547del p.N516Tfs*11 | Frame Shift Del (DEL) | VAF 162/417 reads (39%) | called by mutect2, pindel, varscan2
- PDS5B | c.2170del p.R724Vfs*32 | Frame Shift Del (DEL) | VAF 60/179 reads (34%) | called by mutect2, pindel, varscan2
- PHF13 | c.413del p.G138Afs*3 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.8117del p.N2706Mfs*4 | Frame Shift Del (DEL) | VAF 88/255 reads (35%) | called by mutect2, pindel, varscan2
- PLPPR3 | c.650_651del p.Y217Cfs*102 (on ENST00000520876 / NM_001270366.2; = p.Y217Cfs*130 on NM_024888.2) | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | called by mutect2, pindel, varscan2
- PPT1 | c.166del p.M56Wfs*14 (on ENST00000433473; = p.M57Wfs*14 on NM_000310.4) | Frame Shift Del (DEL) | VAF 107/292 reads (37%) | called by mutect2, pindel, varscan2
- PRAMEF5 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTEN | c.120_123del p.E40Dfs*13 | Frame Shift Del (DEL) | VAF 92/213 reads (43%) | called by mutect2, pindel, varscan2
- RNF8 | c.440del p.N147Ifs*4 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- SECISBP2 | c.770_772del p.E257del | In Frame Del (DEL) | VAF 30/71 reads (42%) | called by mutect2, pindel, varscan2
- SGIP1 | c.996del p.V333Wfs*44 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- SLC10A5 | c.769_770dup p.S258Tfs*5 | Frame Shift Ins (INS) | VAF 15/54 reads (28%) | called by mutect2, varscan2
- SOS1 | c.3090dup p.Y1031Ifs*2 | Frame Shift Ins (INS) | VAF 32/144 reads (22%) | called by mutect2, varscan2
- STAB1 | c.2933del p.P978Lfs*57 | Frame Shift Del (DEL) | VAF 37/97 reads (38%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1318del p.T440Hfs*61 | Frame Shift Del (DEL) | VAF 76/162 reads (47%) | called by mutect2, varscan2
- TASOR | c.1686del p.F562Lfs*21 (on ENST00000355628 / NM_001365636.2; = p.F166Lfs*21 on NM_015224.3) | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- TDRD1 | c.423del p.K141Nfs*2 | Frame Shift Del (DEL) | VAF 39/175 reads (22%) | called by mutect2, pindel, varscan2
- THAP6 | c.171del p.G58Efs*23 | Frame Shift Del (DEL) | VAF 90/224 reads (40%) | called by mutect2, pindel, varscan2
- THRAP3 | c.437_438del p.S146* | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by pindel, varscan2
- TVP23A | c.419_420del p.F140* | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, varscan2
- UBA6 | c.897del p.F299Lfs*8 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | called by mutect2, varscan2
- URB2 | c.4000del p.E1334Rfs*25 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- USF3 | c.2380del p.R794Gfs*2 | Frame Shift Del (DEL) | VAF 61/162 reads (38%) | called by mutect2, pindel, varscan2
- UTP20 | c.5639del p.F1880Sfs*6 | Frame Shift Del (DEL) | VAF 42/111 reads (38%) | called by mutect2, pindel, varscan2
- VAV3 | c.1269_1271del p.F423del | In Frame Del (DEL) | VAF 81/285 reads (28%) | called by pindel, varscan2
- WHAMM | c.1950_1952del p.P658del | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
- ZMYM3 | c.3819del p.K1273Nfs*11 | Frame Shift Del (DEL) | VAF 64/183 reads (35%) | called by mutect2, pindel, varscan2
- ABCG8 | c.456C>T p.R152= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs751273378, COSV55395806; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.297C>T p.A99= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs139823618; called by muse, mutect2, varscan2
- ADGRA2 | c.810C>A p.A270= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV59446534; called by mutect2, varscan2
- AFF2 | c.3183C>A p.P1061= | Silent (SNP) | VAF 83/215 reads (39%) | catalogued as COSV54002567; called by muse, mutect2, varscan2
- AMBRA1 | c.711G>A p.T237= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as rs775404882, COSV54056367; called by muse, mutect2, varscan2
- ARAP2 | c.1884C>T p.T628= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as COSV100394753, COSV58290898; called by muse, mutect2, varscan2
- ARHGAP32 | c.1953G>A p.K651= (on ENST00000310343 / NM_001378025.1; = p.K302= on NM_014715.4) | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as COSV59853820; called by muse, mutect2, varscan2
- ARHGEF5 | c.4008G>A p.S1336= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1457590749, COSV50216952; called by mutect2, varscan2
- BRD3 | c.1885C>T p.L629= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as COSV57705842; called by muse, mutect2, varscan2
- C2orf69 | c.573A>G p.L191= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as COSV60667287; called by muse, mutect2, varscan2
- CA10 | c.501G>A p.T167= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as rs769181729, COSV53362898, COSV99564932; called by muse, mutect2, varscan2
- CASKIN2 | c.3027C>T p.F1009= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs753890852, COSV58599072; called by muse, mutect2
- CCNC | c.558G>A p.T186= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs759045143, COSV58334762; called by muse, mutect2, varscan2
- CD164L2 | c.478C>T p.L160= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs768373343, COSV64995538; called by muse, mutect2, varscan2
- CDK5RAP1 | c.486T>C p.L162= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as rs1254336363, COSV59428459; called by muse, mutect2
- CEP104 | c.2370C>T p.V790= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as rs367968279; called by muse, mutect2, varscan2
- CILP2 | c.72C>A p.T24= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV52279138; called by muse, mutect2, varscan2
- COLGALT1 | c.1806T>C p.R602= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV53111077; called by muse, mutect2, varscan2
- CPLX2 | c.153G>A p.K51= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1172696005, COSV64001874; called by muse, mutect2, varscan2
- CRAMP1 | c.2799T>C p.A933= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV51965238; called by muse, mutect2, varscan2
- CSF3R | c.24C>T p.S8= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV58970440; called by muse, mutect2, varscan2
- CTTN | c.1491C>T p.A497= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as rs770334765, COSV57233393; called by muse, mutect2, varscan2
- DEXI | c.9C>T p.G3= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV59328938; called by muse, mutect2
- DNAH1 | c.9045C>T p.Y3015= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV70234393; called by muse, mutect2, varscan2
- ECT2L | c.1368G>A p.T456= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs762663457, COSV62886497; called by muse, mutect2, varscan2
- EPHA6 | c.15G>A p.S5= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV67589655; called by muse, mutect2, varscan2
- ERBB4 | c.633G>A p.T211= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs142765774; called by muse, mutect2, varscan2
- FAM47C | c.1518C>T p.R506= | Silent (SNP) | VAF 78/191 reads (41%) | catalogued as rs149060980, COSV63723690; called by muse, mutect2, varscan2
- FCGRT | c.693G>A p.L231= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV54543525; called by muse, mutect2, varscan2
- FEN1 | c.993C>T p.S331= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV57251340; called by muse, mutect2, varscan2
- FNBP1 | c.1644C>T p.P548= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as COSV63089666; called by muse, mutect2, varscan2
- FOXL1 | c.183G>A p.A61= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV57214214; called by muse, mutect2
- FRY | c.4044A>G p.T1348= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1056113857, COSV66577012; called by muse, mutect2, varscan2
- FXR2 | c.1299C>T p.G433= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV51469344; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1347G>A p.P449= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs782227868, COSV56087235; called by muse, mutect2, varscan2
- HBS1L | c.477G>A p.V159= | Silent (SNP) | VAF 86/221 reads (39%) | catalogued as COSV59022562; called by muse, mutect2, varscan2
- HERC6 | c.861C>T p.G287= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV52029926; called by muse, mutect2, varscan2
- HS3ST3A1 | c.975C>T p.R325= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs1282796364, COSV52378457; called by muse, mutect2, varscan2
- HS6ST1 | c.1047C>T p.D349= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV52130241; called by muse, mutect2, varscan2
- HTR1A | c.954C>T p.P318= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV60500512; called by muse, mutect2, varscan2
- IGFBP4 | c.660T>C p.D220= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV54098225; called by muse, mutect2, varscan2
- IQCE | c.1113C>T p.C371= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV58080994; called by muse, mutect2, varscan2
- KDM4B | c.1125G>A p.R375= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV50247854; called by muse, mutect2, varscan2
- KDM7A | c.1551T>C p.H517= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV50094450; called by muse, mutect2
- KLF1 | c.63G>A p.P21= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs778818367, COSV53435855; called by muse, mutect2, varscan2
- KRTAP20-2 | c.102C>T p.G34= | Silent (SNP) | VAF 107/265 reads (40%) | catalogued as rs779957350, COSV58183118; called by muse, mutect2, varscan2
- LAMP3 | c.426T>G p.A142= | Silent (SNP) | VAF 233/507 reads (46%) | catalogued as COSV55616528; called by muse, mutect2, varscan2
- LIG3 | c.1332G>A p.S444= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs111958156; called by muse, mutect2, varscan2
- LPCAT1 | c.1311C>T p.G437= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV52040468; called by muse, mutect2, varscan2
- LRRC14B | c.1365C>T p.A455= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs776073523, COSV57256675, COSV57257780; called by muse, mutect2, varscan2
- MADD | c.591G>A p.K197= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV60628706; called by muse, mutect2, varscan2
- MARS1 | c.1971T>C p.A657= | Silent (SNP) | VAF 66/136 reads (49%) | catalogued as COSV56257918; called by muse, mutect2, varscan2
- MFSD11 | c.273C>T p.A91= | Silent (SNP) | VAF 157/378 reads (42%) | catalogued as rs775395625, COSV60627523; called by muse, mutect2, varscan2
- MIDN | c.900G>A p.R300= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV56296548; called by muse, mutect2, varscan2
- MORC1 | c.1455A>G p.Q485= | Silent (SNP) | VAF 101/230 reads (44%) | catalogued as rs758240127, COSV51728294; called by muse, mutect2, varscan2
- MST1R | c.3528T>A p.P1176= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV56572569; called by muse, mutect2, varscan2
- MYO7A | c.1143G>A p.T381= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs781795932, COSV68686577; called by muse, mutect2
- NDUFS5 | c.99C>T p.C33= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV100880480, COSV65892476; called by muse, mutect2, varscan2
- NOMO2 | c.699G>A p.V233= | Silent (SNP) | VAF 121/295 reads (41%) | catalogued as COSV57917858; called by muse, mutect2, varscan2
- NOTCH1 | c.5646C>T p.F1882= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1340810189, COSV53081793; called by muse, mutect2
- NPC1 | c.1533G>A p.T511= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs778890495, COSV52578750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OAT | c.208T>C p.L70= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV64348076; called by muse, mutect2, varscan2
- OR1A2 | c.201C>A p.S67= | Silent (SNP) | VAF 117/254 reads (46%) | catalogued as COSV67936703; called by muse, mutect2, varscan2
- OR52N1 | c.6A>G p.S2= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV57693928; called by muse, mutect2, varscan2
- P2RY2 | c.162G>A p.A54= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs144380076, COSV60777145; called by muse, mutect2
- PCDH19 | c.606G>A p.S202= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs761463596, COSV55267053; called by muse, mutect2, varscan2
- PCDHA10 | c.1350C>T p.N450= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs782631166, COSV56474466, COSV56496941; called by muse, mutect2, varscan2
- PCNX2 | c.2274G>A p.P758= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs199839640; called by muse, mutect2, varscan2
- PDCD11 | c.1863G>A p.E621= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as COSV63934967; called by muse, mutect2, varscan2
- PDE1C | c.585T>G p.R195= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV58525220; called by muse, mutect2, varscan2
- PEAR1 | c.2193T>C p.G731= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV52775229; called by muse, mutect2
- PKHD1L1 | c.9837C>T p.R3279= | Silent (SNP) | VAF 79/194 reads (41%) | catalogued as rs376305342, COSV65741921; called by muse, mutect2, varscan2
- PLCB1 | c.912C>T p.N304= | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as rs374061975; called by muse, mutect2, varscan2
- POLR1A | c.1848G>A p.Q616= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV55698060; called by muse, mutect2, varscan2
- PPP6R1 | c.357G>A p.L119= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV69800521; called by muse, mutect2, varscan2
- PRDM5 | c.765T>A p.T255= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as COSV53365627; called by muse, mutect2, varscan2
- PRKCI | c.1230C>G p.T410= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV55521838; called by muse, mutect2, varscan2
- PRSS16 | c.1230G>A p.V410= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV57916535; called by muse, mutect2, varscan2
- PSMD8 | c.582C>T p.L194= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs772938089, COSV53058468; called by muse, mutect2, varscan2
- PTGER3 | c.468G>A p.A156= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs776804883, COSV60696239; called by muse, mutect2, varscan2
- PTOV1 | c.966G>A p.S322= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs372015619, COSV55589853; called by muse, mutect2, varscan2
- PTPN5 | c.819C>T p.S273= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs533778490, COSV62128031; called by muse, mutect2, varscan2
- RACGAP1 | c.279C>T p.C93= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as rs964211989, COSV56699750; called by muse, mutect2, varscan2
- RPUSD1 | c.225C>T p.C75= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs768427216, COSV50101969; called by muse, mutect2, varscan2
- RYR1 | c.11979C>T p.H3993= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV62107273; called by muse, mutect2, varscan2
- SALL2 | c.1095C>A p.P365= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV58105297; called by muse, mutect2, varscan2
- SELENOW | c.246C>T p.A82= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as rs771386923, COSV72682678; called by muse, mutect2, varscan2
- SH3BP5 | c.468G>A p.Q156= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV53746044; called by muse, mutect2, varscan2
- SIGLEC5 | c.1365C>T p.C455= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs781099888, COSV55782759; called by muse, mutect2, varscan2
- SLC44A1 | c.1539C>A p.T513= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as COSV58266817; called by muse, mutect2, varscan2
- SMCR8 | c.1839C>T p.S613= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV58180413; called by muse, mutect2, varscan2
- SON | c.1512C>T p.T504= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs775925687, COSV51668128; called by muse, mutect2, varscan2
- SPEM2 | c.1491C>T p.T497= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs779400015, COSV61603036; called by muse, mutect2
- SPNS3 | c.571C>T p.L191= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs1353196668, COSV61071571; called by muse, mutect2, varscan2
- TBC1D8 | c.1641C>T p.T547= | Silent (SNP) | VAF 75/188 reads (40%) | catalogued as COSV65215598; called by muse, mutect2, varscan2
- TBX5 | c.894C>T p.S298= | Silent (SNP) | VAF 11/166 reads (7%) | catalogued as rs770206057, COSV59860313, COSV59864330; called by muse, mutect2
- TCF3 | c.423G>A p.S141= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs755661624, COSV53652486; called by muse, mutect2, varscan2
- TECPR2 | c.978C>T p.S326= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs142082203; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM237 | c.873T>C p.I291= (on ENST00000409883 / NM_001044385.3; = p.I283= on NM_152388.4) | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV53806383; called by muse, mutect2, varscan2
- TRPM7 | c.1581C>A p.T527= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV57920635; called by muse, mutect2, varscan2
- TRRAP | c.11367G>A p.T3789= (on ENST00000359863 / NM_001244580.1; = p.T3760= on NM_003496.3) | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs141285775; called by muse, mutect2, varscan2
- TTC23 | c.684A>G p.V228= | Silent (SNP) | VAF 27/251 reads (11%) | catalogued as rs749548710, COSV50441983; called by muse, mutect2, varscan2
- UNC13A | c.3207C>T p.C1069= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs771601640, COSV53206462; called by muse, mutect2, varscan2
- URGCP | c.762C>T p.S254= (on ENST00000453200 / NM_001077663.3; = p.S245= on NM_017920.4) | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs950825333, COSV56248649; called by muse, mutect2, varscan2
- WNT10A | c.735C>T p.H245= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV51463459; called by muse, mutect2
- ZBED1 | c.1917G>A p.A639= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs1435643858, COSV58129934; called by muse, mutect2, varscan2
- ZFYVE9 | c.4215C>T p.C1405= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV55090623, COSV55098318; called by muse, mutect2, varscan2
- ZNF420 | c.1155C>T p.H385= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV58495726; called by muse, mutect2, varscan2
- ZNF607 | c.609G>A p.G203= | Silent (SNP) | VAF 69/168 reads (41%) | catalogued as COSV62206151; called by muse, mutect2, varscan2
- ZP4 | c.190C>T p.L64= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as COSV63913184; called by muse, mutect2, varscan2
- AC005863.1 | n.189C>T | RNA (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- CCDC65 | c.-2C>T | 5'UTR (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99907923; called by muse, varscan2
- CPLANE1 | chr5:37167048 del T | 3'Flank (DEL) | VAF 152/468 reads (32%) | called by mutect2, pindel, varscan2
- ELMO3 | c.1421-8dup | Intron (INS) | VAF 30/57 reads (53%) | catalogued as rs776111360; called by mutect2, varscan2
- KNOP1P1 | n.249del | RNA (DEL) | VAF 27/74 reads (36%) | catalogued as rs762636138; called by mutect2, varscan2
- MSH5 | c.538-46A>G | Intron (SNP) | VAF 19/98 reads (19%) | catalogued as rs767598791, COSV65211042; called by muse, mutect2, varscan2
- RRM2 | n.672C>T | RNA (SNP) | VAF 12/34 reads (35%) | catalogued as rs776733029; called by muse, mutect2, varscan2
- SLMAP | c.1337-1110G>A | Intron (SNP) | VAF 38/91 reads (42%) | catalogued as COSV55851860; called by muse, mutect2, varscan2
- SOHLH1 | c.*638C>T | 3'UTR (SNP) | VAF 17/33 reads (52%) | catalogued as rs370849984; called by muse, mutect2, varscan2
- SPACA6 | chr19:51693309 G>T | 5'Flank (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- TANGO2 | c.56+84C>T | Intron (SNP) | VAF 37/82 reads (45%) | catalogued as rs774267660, COSV59294879; called by muse, mutect2, varscan2
- WASF4P | n.1203C>A | RNA (SNP) | VAF 86/196 reads (44%) | called by muse, mutect2, varscan2
